Gene-level copy-number profile of tumor specimen TCGA-AF-3911-01A from TCGA case TCGA-AF-3911, project TCGA-READ (Rectum Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectum, NOS; AJCC pathologic stage: Stage IIIC; Age at diagnosis: 48.2 years (17,609 days).
Specimen TCGA-AF-3911-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-READ.b487429b-682b-469c-a7f6-cac725a49dbf.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-AF-3911-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/6c6b4d3c-a12f-406f-b985-0ddc9f396b93

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 1,523; copy number 2: 14,729; copy number 3: 31,305; copy number 4: 6,103; copy number 5: 1,570; copy number 6: 1,604; copy number 7: 1,985; copy number 8: 996; copy number 11: 5.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-AF-3911-01A-01D-1732-01): tumor purity 0.72, ploidy 3.18, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 2,986 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:70,972–63,636,617, 1,118 genes, copy number 7 (broad region; genes not listed).
- chr8:38,269,704–38,853,028, 16 genes, copy number 7 (within-gene range 3–7): NSD3, AC087362.2, AC087362.1, AC087623.2, LETM2, FGFR1, AC087623.3, AC087623.1, RPS20P22, C8orf86, AC069120.1, RNF5P1, AC016813.1, TACC1, Y_RNA, AC067817.1.
- chr8:112,148,742–113,436,939, 5 genes, copy number 11 (within-gene range 5–17): RNU4-37P, CSMD3, AC024996.1, RPL30P16, MIR2053.
- chr8:120,059,780–145,066,685, 456 genes, copy number 7 (within-gene range 5–7) (broad region; genes not listed).
- chr13:18,467,172–114,337,626, 1,391 genes, copy number 7–8 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,523. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
